CCDI case PBBTKG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/99a4f09c-8054-4eff-8edd-a66ecae08434

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Craniopharyngioma: ICD-O-3 morphology code: 9350/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.4 years (3,786 days).

Biospecimens (3 samples)
- Sample 0DGUS8: Tissue type: Normal; Specimen type: Peripheral Whole Blood. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0DGUSE: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DGUT9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
